Somatic mutation profile of tumor specimen TCGA-BP-5198-01A (aliquot TCGA-BP-5198-01A-01D-1429-08) from TCGA case TCGA-BP-5198, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.2 years (26,360 days).
Specimen TCGA-BP-5198-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a3b75bd-46df-4228-a2e0-2ecee4d0377b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5198-11A (Solid Tissue Normal), aliquot TCGA-BP-5198-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3deb8ab-2718-4403-ab8e-08b896bf92f1

The open-access MAF lists 80 somatic variants for this specimen: 65 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Frame Shift Del 9, Nonsense Mutation 6, Frame Shift Ins 3, Nonstop Mutation 2, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.3013G>T p.E1005* | Nonsense Mutation (SNP) | VAF 26/177 reads (15%) | catalogued as rs564713154, CM158143, COSV57310876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM19 | c.1502T>A p.M501K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV57423890, COSV57426233; called by muse, mutect2, varscan2
- ATP12A | c.2878T>A p.F960I | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV54513181; called by muse, mutect2, varscan2
- BMPR2 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV65807775; called by muse, mutect2, varscan2
- CD109 | c.3064A>C p.K1022Q | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV54646070; called by muse, mutect2
- CD274 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV67501041; called by muse, mutect2
- CEP83 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60406914; called by muse, mutect2, varscan2
- CNR2 | c.284A>T p.H95L | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65692341; called by muse, mutect2, varscan2
- CORO2A | c.273C>G p.N91K | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV59662212; called by muse, mutect2, varscan2
- CPAMD8 | c.5797T>G p.*1933Eext*? (on ENST00000651564; = p.*1886Eext*? on NM_015692.5) | Nonstop Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV50185227; called by mutect2, varscan2
- CSMD3 | c.7873C>T p.P2625S (on ENST00000297405 / NM_001363185.1; = p.P2521S on NM_052900.3) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52115904; called by muse, mutect2, varscan2
- DENND11 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1261619568, COSV72097600; called by muse, mutect2
- DOT1L | c.4613A>C p.*1538Sext*63 | Nonstop Mutation (SNP) | VAF 41/219 reads (19%) | catalogued as COSV58536478; called by muse, mutect2, varscan2
- FAM209A | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 25/155 reads (16%) | catalogued as rs752842594, COSV54766038; called by muse, mutect2, varscan2
- FANCE | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV57689289; called by muse, mutect2, varscan2
- FAT3 | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs774849735, COSV53082563; called by muse, mutect2
- FKBP11 | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 69/257 reads (27%) | catalogued as COSV56739220; called by muse, mutect2, varscan2
- HIBADH | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55311809; called by muse, mutect2, varscan2
- HSPA6 | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV59060213; called by muse, mutect2, varscan2
- KIAA1549L | c.1157C>A p.T386K (on ENST00000321505; = p.T683K on NM_012194.3) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as COSV55770391, COSV55770553; called by muse, mutect2, varscan2
- LAMC2 | c.1082A>C p.D361A | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV51452912; called by muse, mutect2, varscan2
- LRPPRC | c.3111A>T p.K1037N | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV53234808; called by muse, mutect2, varscan2
- MGAT4B | c.1422C>T p.D474= | Splice Region (SNP) | VAF 20/74 reads (27%) | catalogued as rs552336424, COSV52976965; called by muse, mutect2, varscan2
- MTMR14 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs762006852, COSV56003708; called by muse, mutect2, varscan2
- NECTIN3 | c.556A>T p.N186Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60550124; called by muse, mutect2, varscan2
- NOL11 | c.499T>G p.L167V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV53522396; called by muse, mutect2, varscan2
- NPHP1 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57206817; called by muse, mutect2, varscan2
- OR4Q3 | c.473G>T p.W158L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV100056896, COSV59177508; called by muse, mutect2, varscan2
- PCDHA12 | c.1825T>C p.Y609H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782559386, COSV56481871; called by muse, mutect2, varscan2
- PEG3 | c.4032C>G p.S1344R | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV55626921, COSV99687098; called by muse, mutect2, varscan2
- PI4KA | c.5026G>A p.A1676T | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.95); catalogued as COSV55405680; called by muse, mutect2, varscan2
- PKP2 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50726508, COSV99298133; called by muse, mutect2, varscan2
- PLOD2 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.803); catalogued as rs780062874, COSV51462682; called by muse, mutect2, varscan2
- POLG2 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs146731596; called by muse, mutect2, varscan2
- POM121 | c.1025G>A p.R342H (on ENST00000434423; = p.R77H on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/634 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs782310112, COSV57511657; called by muse, mutect2, varscan2
- RSF1 | c.1914T>A p.C638* | Nonsense Mutation (SNP) | VAF 121/371 reads (33%) | catalogued as COSV57836947; called by muse, mutect2, varscan2
- RTN2 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV55592817; called by muse, mutect2, varscan2
- SETD2 | c.7114_7121del p.T2372Sfs*54 | Frame Shift Del (DEL) | VAF 104/262 reads (40%) | catalogued as COSV57431705; called by mutect2, pindel, varscan2
- SLC24A4 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | catalogued as COSV54108376; called by muse, mutect2, varscan2
- TMEM132E | c.701G>A p.S234N (on ENST00000321639; = p.S324N on NM_001304438.2) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58695114; called by muse, mutect2, varscan2
- TMPRSS6 | c.2308G>C p.G770R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60975576; called by muse, mutect2, varscan2
- TTN | c.8704G>T p.E2902* (on ENST00000591111; = p.E2856* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 32/248 reads (13%) | catalogued as COSV59914847; called by muse, mutect2, varscan2
- USP22 | c.1148G>A p.C383Y | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54945705; called by muse, mutect2, varscan2
- WDR36 | c.548T>G p.I183S | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV72411051; called by muse, mutect2, varscan2
- WDR64 | c.1047G>T p.L349F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63793160; called by muse, mutect2, varscan2
- WIPF2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs761403770, COSV60272466; called by muse, mutect2, varscan2
- XIRP2 | c.1325C>A p.T442N (on ENST00000628543; = p.T617N on NM_152381.6) | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54685810, COSV99738796; called by muse, mutect2, varscan2
- YEATS4 | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56088220; called by muse, mutect2, varscan2
- ZNF267 | c.1866T>G p.H622Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56250921; called by muse, mutect2, varscan2
- ZNF616 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs777378939, COSV57509555; called by muse, mutect2, varscan2
- ZNFX1 | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV65574054; called by muse, mutect2, varscan2
- ACIN1 | c.2450_2456del p.P817Hfs*53 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.2258del p.P753Rfs*6 | Frame Shift Del (DEL) | VAF 39/192 reads (20%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.1082del p.G361Afs*9 (on ENST00000651564; = p.G314Afs*9 on NM_015692.5) | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel
- HERC1 | c.8773_8774dup p.N2925Kfs*3 | Frame Shift Ins (INS) | VAF 68/296 reads (23%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, varscan2
- LRIG3 | c.2911del p.Y971Tfs*24 | Frame Shift Del (DEL) | VAF 58/195 reads (30%) | called by mutect2, pindel, varscan2
- MAP2K2 | c.960_962del p.E320_L321delinsD | In Frame Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- OTUD7A | c.343del p.S115Pfs*42 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- P2RX2 | c.1004dup p.F336Vfs*9 (on ENST00000343948 / NM_170683.4; = p.F264Vfs*9 on NM_012226.5) | Frame Shift Ins (INS) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2929_2930del p.I977Rfs*4 | Frame Shift Del (DEL) | VAF 118/335 reads (35%) | called by pindel, varscan2
- RAB6D | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RPAP1 | c.1543del p.A515Qfs*40 | Frame Shift Del (DEL) | VAF 19/112 reads (17%) | called by mutect2, pindel, varscan2
- TAF2 | c.3543_3544insT p.T1182Yfs*37 | Frame Shift Ins (INS) | VAF 39/252 reads (15%) | called by mutect2, pindel, varscan2
- VHL | c.482_485del p.R161Pfs*8 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP15 | c.138C>T p.L46= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs765456843, COSV54481446; called by muse, mutect2, varscan2
- DIAPH1 | c.1626C>A p.S542= | Silent (SNP) | VAF 45/191 reads (24%) | catalogued as COSV53879207; called by muse, mutect2, varscan2
- DPYSL4 | c.792C>A p.I264= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV58306167; called by muse, mutect2, varscan2
- DUS2 | c.954C>A p.A318= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV62707972; called by muse, mutect2, varscan2
- GTF3C1 | c.1068A>G p.T356= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as COSV62239348; called by muse, mutect2, varscan2
- LRP12 | c.1683T>A p.V561= | Silent (SNP) | VAF 50/226 reads (22%) | catalogued as COSV52626180; called by muse, mutect2, varscan2
- MACF1 | c.18684C>A p.A6228= (on ENST00000372915; = p.A4273= on NM_012090.5) | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV57109506; called by muse, mutect2, varscan2
- MTMR9 | c.66C>T p.Y22= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV55310869; called by muse, mutect2, varscan2
- MYO10 | c.2841C>T p.F947= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs775378841, COSV57017674; called by muse, mutect2, varscan2
- PCNX1 | c.2613T>C p.S871= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV53090375; called by muse, mutect2, varscan2
- PRAMEF14 | c.1341C>T p.P447= | Silent (SNP) | VAF 92/287 reads (32%) | catalogued as COSV100577270; called by muse, mutect2, varscan2
- RANBP3 | c.33C>G p.A11= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV50380401; called by muse, mutect2
- SLC4A1 | c.1716C>T p.L572= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as COSV52258706; called by muse, mutect2, varscan2
- ZSCAN2 | c.276A>T p.V92= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV59107328; called by muse, mutect2
- VPS13A | c.9189+2560T>C | Intron (SNP) | VAF 19/90 reads (21%) | catalogued as rs1307782917, COSV100652319; called by muse, mutect2
